Somatic mutation profile of tumor specimen TCGA-FP-8211-01A (aliquot TCGA-FP-8211-01A-11D-2340-08) from TCGA case TCGA-FP-8211, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.9 years (22,957 days).
Specimen TCGA-FP-8211-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d8c584d-e827-4b4e-8aa4-12b9c9744d2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-8211-10A (Blood Derived Normal), aliquot TCGA-FP-8211-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d9e228-aec5-452d-9dbb-00dde47a4d1c

The open-access MAF lists 113 somatic variants for this specimen: 93 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 18, Nonsense Mutation 8, Frame Shift Del 8, In Frame Del 2, Frame Shift Ins 1, RNA 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIN2 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV99909380; called by muse, mutect2, varscan2
- C10orf53 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as rs1160182669, COSV65108874; called by muse, mutect2
- C12orf50 | c.974A>T p.K325I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV53893760, COSV53896253; called by muse, mutect2, varscan2
- C22orf23 | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as COSV50778017; called by muse, mutect2, varscan2
- CD163 | c.1054A>G p.K352E | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.912); catalogued as COSV63133731; called by muse, mutect2, varscan2
- CD46 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59733928; called by muse, mutect2, varscan2
- CD81 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55133278; called by muse, mutect2, varscan2
- CDH2 | c.1020A>G p.E340= | Splice Region (SNP) | VAF 18/138 reads (13%) | catalogued as COSV52283841; called by muse, mutect2, varscan2
- CDH23 | c.4153T>C p.Y1385H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV56470962; called by muse, mutect2, varscan2
- CDHR2 | c.2887G>A p.V963I | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs756472116, COSV56136062; called by muse, mutect2, varscan2
- CHRNB4 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 80/425 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.191); catalogued as rs775858779, COSV55716492; called by muse, mutect2, varscan2
- COPE | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53230992; called by muse, mutect2, varscan2
- CP | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs755243937, COSV52829936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF1R | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV53836683; called by muse, mutect2, varscan2
- CUL1 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57388522; called by muse, mutect2, varscan2
- DDX3Y | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV60176985; called by muse, mutect2, varscan2
- DLX1 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV59394711; called by muse, mutect2, varscan2
- DNAJB1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs768130288, COSV54317227, COSV54317299; called by muse, mutect2, varscan2
- DOK7 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60772638; called by muse, mutect2, varscan2
- ELAVL2 | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as COSV56363971, COSV99807254; called by muse, mutect2, varscan2
- EPHA6 | c.2723T>G p.V908G (on ENST00000389672 / NM_001080448.3; = p.V300G on NM_173655.4) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67577075; called by muse, mutect2
- FAT1 | c.10316T>C p.V3439A | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV71674693; called by muse, mutect2, varscan2
- FSCB | c.1864G>T p.V622F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs1186803978, COSV61218522; called by muse, varscan2
- GIMAP6 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV61033809, COSV61034862; called by muse, mutect2, varscan2
- GPR161 | c.792C>G p.N264K | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.265); catalogued as COSV54791565; called by muse, mutect2, varscan2
- GPR83 | c.439A>C p.S147R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54718503, COSV54719112; called by muse, mutect2, varscan2
- GRM3 | c.1023C>A p.N341K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV64473785; called by muse, mutect2, varscan2
- HMBS | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1278115874, COSV53828965; called by muse, mutect2, varscan2
- IGDCC3 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV60077211, COSV60078176; called by muse, mutect2, varscan2
- INTS5 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.432); catalogued as COSV57952114; called by muse, mutect2, varscan2
- ITGAE | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.152); catalogued as COSV53995511; called by muse, mutect2, varscan2
- ITIH4 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs572371573, COSV56575409; called by muse, mutect2, varscan2
- ITPRID1 | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 47/127 reads (37%) | catalogued as rs756146204, COSV60076292; called by muse, mutect2, varscan2
- ITSN1 | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1357531112, COSV67157140; called by muse, mutect2
- KANK1 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63213019; called by muse, mutect2, varscan2
- KLC2 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57583111; called by muse, varscan2
- KRT84 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV57772149; called by muse, mutect2, varscan2
- LHX3 | c.160A>T p.K54* (on ENST00000371748 / NM_178138.6; = p.K59* on NM_014564.5) | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV65582245; called by muse, mutect2, varscan2
- LPA | c.5502A>T p.Q1834H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV60298048, COSV60302164, COSV60303870; called by muse, mutect2, varscan2
- MYCL | c.164C>T p.A55V (on ENST00000372816 / NM_001033081.3; = p.A85V on NM_005376.5) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs767668202, COSV65693417; called by muse, mutect2
- MYH15 | c.3574G>T p.E1192* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as COSV56312703; called by muse, mutect2, varscan2
- MYO15A | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52758672; called by muse, mutect2, varscan2
- NBEA | c.6053A>G p.E2018G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59794160; called by muse, mutect2
- NBEA | c.8161G>C p.D2721H | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV59794175; called by muse, mutect2, varscan2
- NR4A2 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 38/108 reads (35%) | catalogued as COSV59894313; called by muse, mutect2, varscan2
- NRXN3 | c.2840G>A p.R947H (on ENST00000335750 / NM_001330195.2; = p.R574H on NM_004796.6) | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.584); catalogued as rs140528152; called by muse, mutect2, varscan2
- OR1L3 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.491); catalogued as rs1201543580, COSV59169969; called by muse, mutect2, varscan2
- PADI6 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV61885023; called by muse, mutect2, varscan2
- PCDH10 | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV52094423; called by muse, mutect2
- PHF20L1 | c.1838G>A p.S613N | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55194203; called by muse, varscan2
- PLD1 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100578109; called by muse, mutect2, varscan2
- PPAT | c.383C>G p.A128G | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as COSV51704800; called by muse, mutect2, varscan2
- PRLR | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs865977247, COSV51496919; called by muse, mutect2
- PRUNE2 | c.4027G>T p.E1343* | Nonsense Mutation (SNP) | VAF 25/39 reads (64%) | catalogued as COSV65042917, COSV65044699; called by muse, mutect2, varscan2
- PTBP1 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV62460559; called by muse, mutect2
- RASGEF1C | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763228959, COSV63181529; called by muse, mutect2, varscan2
- RHBG | c.992C>A p.S331* | Nonsense Mutation (SNP) | VAF 44/147 reads (30%) | catalogued as COSV54806247; called by muse, mutect2, varscan2
- RORC | c.372G>C p.Q124H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs1413632721, COSV100561997, COSV59093646; called by muse, mutect2, varscan2
- RSPO4 | c.306C>A p.D102E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54082480; called by muse, mutect2, varscan2
- RTL5 | c.1499T>A p.I500K | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV65453873; called by muse, mutect2, varscan2
- RYR1 | c.14103G>C p.Q4701H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as COSV62100721; called by muse, mutect2, varscan2
- SCAF4 | c.1601T>C p.I534T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54588559; called by muse, mutect2, varscan2
- SEL1L3 | c.2489C>G p.A830G | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.959); catalogued as COSV53542135, COSV53543237; called by muse, mutect2, varscan2
- SEPTIN14 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs778731243, COSV66428415; called by muse, mutect2, varscan2
- SETD5 | c.2830C>G p.L944V | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs576486238, COSV56712929; called by muse, mutect2, varscan2
- SLC2A3 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.021); catalogued as COSV50003949, COSV99307017; called by muse, mutect2, varscan2
- SP4 | c.2115G>C p.K705N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56023696; called by muse, mutect2, varscan2
- SPTBN5 | c.6220A>C p.T2074P | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV58022834; called by muse, mutect2, varscan2
- TEAD4 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63281455; called by muse, mutect2, varscan2
- TMUB2 | c.793A>T p.S265C (on ENST00000538716 / NM_001353177.2; = p.S245C on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV60229054; called by muse, mutect2, varscan2
- TRPM5 | c.1132T>G p.C378G | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV50158523; called by muse, mutect2, varscan2
- TSEN2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1198220539, COSV53189367; called by muse, mutect2, varscan2
- TSEN2 | c.1017C>G p.F339L | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53189374; called by muse, mutect2, varscan2
- TTLL4 | c.3019G>T p.V1007F | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV51437008; called by muse, mutect2, varscan2
- VPREB1 | c.211T>A p.Y71N | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56425862; called by muse, mutect2, varscan2
- VPS51 | c.995C>G p.A332G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV54207996; called by muse, mutect2, varscan2
- WDR90 | c.2999C>A p.A1000D | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV53471267; called by muse, mutect2, varscan2
- ZBTB11 | c.1652A>G p.K551R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV57245529; called by muse, mutect2, varscan2
- ZNF423 | c.2278T>C p.C760R (on ENST00000563137 / NM_001379286.1; = p.C752R on NM_015069.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52193492; called by muse, mutect2, varscan2
- ZNF536 | c.941A>G p.E314G | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV62826375; called by muse, mutect2, varscan2
- ZNF682 | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV62067509; called by muse, mutect2, varscan2
- ADCY10 | c.1571_1594del p.Q524_Y531del | In Frame Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel
- APC | c.4356_4395del p.P1453Dfs*7 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel
- CCDC180 | c.868_918del p.L290_T306del | In Frame Del (DEL) | VAF 35/73 reads (48%) | called by mutect2, pindel
- HTT | c.5230_5254del p.L1744* | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel
- ILDR1 | c.885_888del p.N295Kfs*40 (on ENST00000344209 / NM_001199799.2; = p.N251Kfs*40 on NM_175924.4) | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- KIAA1841 | c.1282_1292del p.S428Yfs*11 | Frame Shift Del (DEL) | VAF 66/149 reads (44%) | called by mutect2, pindel, varscan2
- NBPF26 | c.2605G>T p.V869L (on ENST00000620612; = p.V607L on NM_001351372.1) | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- NCAM2 | c.521del p.L174Pfs*55 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- NF1 | c.785_789delinsTTTT p.R262Lfs*19 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | called by pindel, varscan2*
- NUP42 | c.373del p.E125Rfs*17 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | called by mutect2, pindel*, varscan2
- PTEN | c.693dup p.T232Hfs*11 | Frame Shift Ins (INS) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- SLAMF8 | c.838del p.V281Cfs*140 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- AGBL1 | c.2277A>G p.Q759= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV66861490; called by muse, mutect2, varscan2
- ANKDD1A | c.150G>T p.V50= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV60353623; called by muse, mutect2, varscan2
- ATP13A5 | c.3180C>T p.F1060= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs751880044, COSV60870708; called by muse, mutect2, varscan2
- BIN2 | c.1494C>A p.S498= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99909383; called by muse, mutect2, varscan2
- BTK | c.198A>T p.T66= | Silent (SNP) | VAF 118/188 reads (63%) | catalogued as COSV58120922; called by muse, mutect2, varscan2
- CABS1 | c.87G>T p.G29= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV56733855; called by muse, mutect2, varscan2
- CTSO | c.504T>C p.Y168= | Silent (SNP) | VAF 76/125 reads (61%) | catalogued as COSV70809308; called by muse, mutect2, varscan2
- CUL4A | c.640T>C p.L214= (on ENST00000375440 / NM_001008895.4; = p.L114= on NM_003589.3) | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV58373676; called by muse, mutect2, varscan2
- GPR149 | c.309T>C p.F103= | Silent (SNP) | VAF 7/177 reads (4%) | called by muse, mutect2
- IGFN1 | c.3087T>G p.V1029= (on ENST00000295591 / NM_001367841.1; = p.V3486= on NM_001164586.2) | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV55175041; called by muse, mutect2
- LRRC14 | c.867C>G p.L289= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV52880141; called by muse, mutect2, varscan2
- MFSD11 | c.555T>A p.V185= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs771566399, COSV60625005; called by muse, mutect2, varscan2
- MTMR14 | c.612A>C p.R204= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV56005568; called by muse, mutect2, varscan2
- NFAT5 | c.3288A>C p.P1096= | Silent (SNP) | VAF 77/195 reads (39%) | catalogued as COSV63028648; called by muse, mutect2, varscan2
- OR4A15 | c.822T>G p.T274= | Silent (SNP) | VAF 25/306 reads (8%) | catalogued as COSV59035832; called by muse, mutect2
- PCDHGB1 | c.1686G>A p.A562= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV53968114; called by muse, mutect2, varscan2
- PLD1 | c.549G>T p.L183= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV60570975; called by muse, mutect2, varscan2
- ZNF696 | c.591C>T p.L197= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs925655216, COSV57525102; called by muse, mutect2, varscan2
- MIR329-1 | n.29C>T | RNA (SNP) | VAF 88/131 reads (67%) | called by muse, mutect2, varscan2
- PATZ1 | c.1335+1465G>T | Intron (SNP) | VAF 30/98 reads (31%) | catalogued as COSV99315051; called by muse, mutect2, varscan2
